Somatic mutation profile of tumor specimen ALCH-B45N-TTP1-A (aliquot ALCH-B45N-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B45N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.5 years (25,747 days).
Specimen ALCH-B45N-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 656bd10f-27b0-42b8-8854-fa37ec9bfa00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B45N-NB1-A (Blood Derived Normal), aliquot ALCH-B45N-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23f04273-2713-4073-9c53-cb1467288e68

The open-access MAF lists 30 somatic variants for this specimen: 19 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 9, Nonsense Mutation 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 70/1468 reads (5%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 118/667 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRINP3 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV66544168; called by muse, mutect2
- BRPF3 | c.2695C>T p.L899F | Missense Mutation (SNP) | VAF 32/640 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1353374004; called by muse, mutect2
- COX7B2 | c.99T>A p.D33E | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as rs951356261; called by muse, mutect2
- FLNC | c.3893C>T p.A1298V | Missense Mutation (SNP) | VAF 34/408 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.262); catalogued as rs1064796931; ClinVar: uncertain significance; called by muse, mutect2
- NADK | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 26/492 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs1429497327; called by muse, mutect2
- RAI14 | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs1466388409; called by muse, mutect2
- SLC25A22 | c.562A>G p.K188E | Missense Mutation (SNP) | VAF 23/349 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs767949941; ClinVar: uncertain significance; called by muse, mutect2
- SLC4A5 | c.2836C>G p.P946A | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1323233833, COSV61030387; called by muse, mutect2
- TRPC3 | c.1051C>T p.R351* (on ENST00000379645 / NM_001366479.2; = p.R278* on NM_003305.2) | Nonsense Mutation (SNP) | VAF 31/550 reads (6%) | catalogued as rs1403632056, COSV53376284; called by muse, mutect2
- ADGRA3 | c.2923T>A p.S975T | Missense Mutation (SNP) | VAF 50/706 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.138); called by muse, mutect2
- DNAH9 | c.3655G>A p.E1219K | Missense Mutation (SNP) | VAF 54/701 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- GUCY1A2 | c.1374G>T p.Q458H | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- KIAA2012 | c.3119A>T p.Q1040L | Missense Mutation (SNP) | VAF 58/962 reads (6%) | SIFT deleterious (0); called by muse, mutect2
- LATS1 | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 29/532 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- LATS1 | c.1253A>G p.N418S | Missense Mutation (SNP) | VAF 31/367 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MYH8 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 68/1205 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.2); called by muse, mutect2
- OR8B12 | c.592G>C p.V198L | Missense Mutation (SNP) | VAF 17/246 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.019); called by muse, mutect2
- ATP5F1D | c.213G>T p.A71= | Silent (SNP) | VAF 39/385 reads (10%) | called by muse, mutect2, varscan2
- CCDC191 | c.729G>A p.K243= | Silent (SNP) | VAF 64/883 reads (7%) | called by muse, mutect2
- FIGNL2 | c.1446C>T p.C482= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- GUCY2D | c.1963A>C p.R655= | Silent (SNP) | VAF 45/773 reads (6%) | called by muse, mutect2
- HELB | c.2827A>C p.R943= | Silent (SNP) | VAF 56/604 reads (9%) | called by muse, mutect2
- MANEA | c.735T>C p.Y245= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs1038005375; called by mutect2, varscan2
- OR8B12 | c.591G>T p.V197= | Silent (SNP) | VAF 17/243 reads (7%) | called by muse, mutect2
- PCDH8 | c.1500G>A p.P500= | Silent (SNP) | VAF 22/323 reads (7%) | called by muse, mutect2
- PPP1R3F | c.1404G>A p.G468= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- REXO4 | c.572+117G>A | Intron (SNP) | VAF 50/696 reads (7%) | catalogued as rs782057048; called by muse, mutect2
- Z85994.1 | n.98C>T | RNA (SNP) | VAF 26/434 reads (6%) | catalogued as rs948811163; called by muse, mutect2
